Gene-level copy-number profile of tumor specimen ALCH-B4F0-TTP1-A from ALCHEMIST case ALCH-B4F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 79.9 years (29,187 days).
Specimen ALCH-B4F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96fbce19-5a0f-43b1-850a-7515c5b63f12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4F0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/690fbfcb-ef90-4c4c-acf8-89bc383d1945

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 4,356; copy number 2: 53,775; copy number 3: 730; copy number 4: 39; copy number 5: 2; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,617,170–204,685,738, 3 genes: LRRN2, AL512306.2, AL161793.1.
- chr11:1,074,875–1,110,511, 1 gene: MUC2.
- chr14:104,753,147–104,795,751, 3 genes: SIVA1, AL583722.1, AKT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,007,881–24,008,519, 1 gene, copy number 5: AL590609.1.
- chr12:123,441,517–123,473,154, 2 genes, copy number 6 (within-gene range 2–6): COPS5P2, SNRNP35.
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.

Autosomal genes at a single copy (total copy number 1): 1,502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
